Surgical pathology report (de-identified scan), TCGA case TCGA-06-0178, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0178-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, 1, FRONTAL LESION, EXCISION: GLIOBLASTOMA, FOCAL.
B. BRAIN, 2, FRONTAL LESION, EXCISION: GLIOBLASTOMA, PREDOMINANTLY SOLID.
C. BRAIN, 3, FRONTAL LESION, EXCISION: GLIOBLASTOMA, MOSTLY INFILTRATIVE.
D. BRAIN, 4, DEEP FRONTAL, EXCISION: GLIOBLASTOMA, SOLID AND INFILTRATIVE.

SEE COMMENT.

Operation/Specimen: Frontal lesion; deep frontal lesion.

Clinical History and Pre-Op Dx: [REDACTED] complaining of headache for one month, underwent excisional biopsies of large frontal cystic mass with ring enhancement and edema, with extension through the corpus callosum. The biopsies were diagnosed as glioblastoma multiforme. Current surgery for debulking.

GROSS PATHOLOGY: Four parts.

A.

SPECIMEN: 1, frontal lesion.
FIXATIVE: Formalin.
GENERAL: A 2.5 x 1.5 x 1.0 cm., 1.5 gm., gray-tan to brown portion of brain tissue. Sectioned.
SECTIONS: 1 - all submitted.

B.

SPECIMEN: 2, frontal lesion.
FIXATIVE: Formalin.
GENERAL: A 2.5 x 2.0 x 2.0 cm., 4.5 gm. gray-tan portion of tissue. Sectioned.
SECTIONS: 2-4 - all submitted.

C.

SPECIMEN: 3, frontal lesion.
FIXATIVE: Formalin.
GENERAL: Four irregular red-tan to gray-tan tissue fragments ranging from 1.5 x 1.0 x 0.8 cm. to 2.5 x 2.0 x 1.0 cm. They have a combined weight of 4.45 gm.
SECTIONS: 5,6 - representative.

[page 2 of 2]
SPECIMEN: 4, deep frontal.
FIXATIVE: Formalin.
GENERAL: A 3.5 x 3.0 x 1.5 cm aggregate of two irregularly
shaped, red-brown to gray-tan soft tissue fragments.
They have a combined weight of 4.6 gm. Sectioned.
SECTIONS: 7,8 - representative.

TCCA-06-0178

COMMENT: The specimen is cerebral cortex and white matter diffusely infiltrated and extensively effaced by a glial neoplastic proliferation with nuclear anaplasia, brisk mitotic activity, and focal microvascular cellular proliferation and/or necrosis. The neoplasm is present in all the specimens throughout.

Source: NCI Genomic Data Commons file b67c9d53-5458-4adf-9916-2849c484acb2 (TCGA-06-0178.EFA462F1-142C-45DE-8234-7F9B12D7B701.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).